Somatic mutation profile of tumor specimen TCGA-V4-A9EF-01A (aliquot TCGA-V4-A9EF-01A-21D-A39W-08) from TCGA case TCGA-V4-A9EF, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 56.8 years (20,763 days).
Specimen TCGA-V4-A9EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02942c7f-fa8e-4ffe-bfe4-d4500f7b6a40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EF-10A (Blood Derived Normal), aliquot TCGA-V4-A9EF-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693eebff-7d5e-40c1-a0c5-37dc1d359335

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.669C>G p.Y223* | Nonsense Mutation (SNP) | VAF 36/37 reads (97%) | catalogued as COSV56240406; called by muse, mutect2, varscan2
- BMP1 | c.2200G>A p.V734I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs148552467; called by muse, varscan2
- MYOF | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs762578223, COSV63700907; called by muse, mutect2, varscan2
- C12orf50 | c.234T>A p.H78Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.277); called by muse, varscan2
- C12orf71 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DCPS | c.339del p.Y113* | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
